MMRF case MMRF_1510 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/dfbc5887-a5a6-486f-b273-7c3718996975

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.6 years (21,402 days); ISS stage: III; Days to last known disease status: 1,352 days (3.7 years); Days to last follow up: 1,352 days (3.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 240 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 281 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 726 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 245 days; Days to treatment end: 281 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 726 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: M Protein 3.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.573 mg/dL; Immunoglobulin G 33.4 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 7.05 µg/mL; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 9.3 g/dL; Glucose 9.35 mmol/L; C-Reactive Protein 0.31 mg/dL.
- Day 84 (ECOG 0): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.904 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 6.81 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 69 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 9.08 mmol/L.
- Day 154 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.611 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.803 mg/dL; Immunoglobulin G 5.58 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 143 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.5 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 7.32 mmol/L.
- Day 240 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.921 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 5.94 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 6.11 mmol/L.
- Day 366 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 7.73 g/L; Immunoglobulin A 2.35 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 2.46 µg/mL; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 13.4 mmol/L.
- Day 429 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 8.32 g/L; Immunoglobulin A 2.12 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 5.06 mmol/L.
- Day 555 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Immunoglobulin G 8.62 g/L; Immunoglobulin A 2 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.01 mmol/L.
- Day 602 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 9.08 g/L; Immunoglobulin A 2.86 g/L; Immunoglobulin M 0.5 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 7.48 mmol/L.
- Day 736 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 8.08 g/L; Immunoglobulin A 2.14 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 6.99 mmol/L.
- Day 786 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 8.54 g/L; Immunoglobulin A 2.07 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 2.01 µg/mL; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 7.65 mmol/L.
- Day 891 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 2.11 g/L; Immunoglobulin M 0.58 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.53 mmol/L; Albumin 47 g/L; Total Protein 7.7 g/dL; Glucose 5.01 mmol/L.
- Day 982 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.54 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 2.4 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 2.24 µg/mL; Lactate Dehydrogenase 1.72 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 8.36 mmol/L.
- Day 1,092 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.27 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 4.27 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 1.98 µg/mL; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 4.73 mmol/L.
- Day 1,181: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.34 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.52 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.89 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 8.42 mmol/L.
- Day 1,247: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.97 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 2.85 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 6.38 mmol/L.
- Day 1,352: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.98 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 2.36 g/L; Immunoglobulin M 2.36 g/L; Lactate Dehydrogenase 1.75 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 7.26 mmol/L.

Other clinical attributes
- Day 0: Weight: 91 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1510_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1510_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
